Somatic mutation profile of tumor specimen TCGA-B9-4115-01A (aliquot TCGA-B9-4115-01A-01D-1252-08) from TCGA case TCGA-B9-4115, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 53.6 years (19,571 days).
Specimen TCGA-B9-4115-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70564056-eefa-4081-afa6-081583763410.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-4115-10A (Blood Derived Normal), aliquot TCGA-B9-4115-10A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbd07c29-e182-4b26-83b3-817f42cb7f6c

The open-access MAF lists 57 somatic variants for this specimen: 40 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 30, Silent 17, Frame Shift Del 6, Splice Site 1, Nonsense Mutation 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAA1 | c.214G>C p.V72L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs756284410, COSV57180161; called by muse, mutect2, varscan2
- AGO1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV64596484; called by muse, mutect2, varscan2
- ALDH16A1 | c.2068A>T p.T690S | Missense Mutation (SNP) | VAF 195/540 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as CM142280, COSV53196629; called by muse, mutect2, varscan2
- ARHGEF28 | c.2248G>C p.G750R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV55264986, COSV55269258; called by muse, mutect2, varscan2
- ATP11A | c.2926G>A p.A976T | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as rs140812688, COSV99369648; called by muse, mutect2, varscan2
- ATP11A | c.2927C>G p.A976G | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.02); catalogued as COSV52123870; called by muse, mutect2, varscan2
- ATPSCKMT | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.476); catalogued as rs768653145, COSV54725446; called by muse, mutect2, varscan2
- CACNA1I | c.4005T>G p.C1335W | Missense Mutation (SNP) | VAF 79/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60818248; called by muse, mutect2, varscan2
- CBFA2T2 | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as COSV60075811; called by muse, mutect2, varscan2
- CES4A | c.990C>A p.D330E | Missense Mutation (SNP) | VAF 137/377 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.088); catalogued as COSV58657867, COSV58658138; called by muse, mutect2, varscan2
- CNTNAP1 | c.2250C>A p.D750E | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs770900986, COSV52854237; called by muse, mutect2
- DOCK9 | c.4744A>G p.T1582A (on ENST00000376460 / NM_001366676.2; = p.T1583A on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59642573; called by muse, mutect2, varscan2
- ERMP1 | c.2012T>A p.F671Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV53039488; called by muse, mutect2, varscan2
- HIPK2 | c.1921A>G p.T641A | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV61232483; called by muse, mutect2, varscan2
- HTATSF1 | c.2129A>T p.E710V | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.278); catalogued as COSV54481170; called by muse, mutect2, varscan2
- IRF6 | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65420378; called by muse, mutect2, varscan2
- KAT7 | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 96/400 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV52016871; called by muse, mutect2, varscan2
- KIF12 | c.607T>A p.F203I (on ENST00000640217; = p.F65I on NM_138424.1) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV65118175; called by muse, mutect2, varscan2
- KIF6 | c.2309C>A p.P770Q | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as COSV54693726; called by muse, mutect2, varscan2
- MACF1 | c.18432T>G p.N6144K (on ENST00000372915; = p.N4189K on NM_012090.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as rs1274814932, COSV57143070; called by muse, mutect2, varscan2
- NR2E1 | c.580T>G p.F194V | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV64562734; called by muse, mutect2, varscan2
- NUP210 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1254117174, COSV54413750; called by muse, mutect2, varscan2
- OTUB1 | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 126/462 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV56840140; called by muse, varscan2
- PRKCE | c.268G>C p.G90R | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV60329289; called by muse, mutect2, varscan2
- REV1 | c.3482G>A p.G1161E | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51490231; called by muse, mutect2, varscan2
- SEC24A | c.739+1G>A p.X247_splice | Splice Site (SNP) | VAF 49/132 reads (37%) | catalogued as COSV59749787; called by muse, mutect2, varscan2
- SHROOM1 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV60582489; called by muse, mutect2, varscan2
- SPOCK1 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV56465750; called by muse, mutect2, varscan2
- TMC5 | c.2425T>G p.F809V (on ENST00000396229 / NM_001105248.1; = p.F563V on NM_024780.5) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54909607; called by muse, mutect2, varscan2
- TYRP1 | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs756589047, COSV66358513; called by muse, mutect2, varscan2
- ZFYVE26 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV61331417, COSV61333378; called by mutect2, varscan2
- ZNF134 | c.216C>A p.H72Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV68696887; called by muse, mutect2, varscan2
- BTN3A2 | c.692del p.K231Rfs*47 | Frame Shift Del (DEL) | VAF 63/202 reads (31%) | called by mutect2, pindel, varscan2
- CEP192 | c.2536del p.Y846Mfs*16 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- COX7A1 | c.149_151del p.N50del | In Frame Del (DEL) | VAF 56/214 reads (26%) | called by pindel, varscan2
- CTBP1 | c.150del p.V51Wfs*17 | Frame Shift Del (DEL) | VAF 64/274 reads (23%) | called by mutect2, pindel, varscan2
- ERF | c.1474_1475insTTT p.D491_C492insF | In Frame Ins (INS) | VAF 72/236 reads (31%) | called by mutect2, pindel, varscan2
- MARF1 | c.2315del p.F772Sfs*27 | Frame Shift Del (DEL) | VAF 57/206 reads (28%) | called by mutect2, pindel, varscan2
- MAST4 | c.2565_2575del p.K855Nfs*7 (on ENST00000403625 / NM_001164664.2; = p.K666Nfs*7 on NM_015183.3) | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- OSBPL5 | c.329del p.K110Rfs*12 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | called by mutect2, varscan2
- ATP1A2 | c.2196C>A p.G732= | Silent (SNP) | VAF 94/229 reads (41%) | catalogued as COSV63405770; called by muse, mutect2, varscan2
- CCDC102A | c.240G>T p.L80= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV50779423; called by muse, mutect2, varscan2
- DICER1 | c.5724C>A p.A1908= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV58627859; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.252T>C p.L84= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV64325233; called by muse, mutect2, varscan2
- GASK1B | c.126T>A p.T42= | Silent (SNP) | VAF 111/290 reads (38%) | catalogued as COSV56711691; called by muse, mutect2, varscan2
- HPSE | c.351C>T p.Y117= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs764129564, COSV60988707; called by muse, mutect2, varscan2
- HTT | c.5472C>T p.S1824= | Silent (SNP) | VAF 10/242 reads (4%) | catalogued as COSV61868893; called by muse, mutect2
- IGSF9B | c.345G>T p.V115= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV58072590; called by muse, mutect2, varscan2
- ITPKC | c.345A>T p.P115= | Silent (SNP) | VAF 62/195 reads (32%) | catalogued as COSV54577282; called by muse, mutect2, varscan2
- MCOLN3 | c.1017T>C p.N339= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1458610205, COSV62015929; called by muse, mutect2, varscan2
- PIGV | c.534C>T p.F178= | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as rs1392626425, COSV50304112; called by muse, mutect2, varscan2
- SIVA1 | c.165C>T p.D55= | Silent (SNP) | VAF 92/308 reads (30%) | catalogued as COSV57332217; called by muse, mutect2, varscan2
- SLC9A1 | c.1842G>A p.L614= | Silent (SNP) | VAF 67/252 reads (27%) | catalogued as COSV56056677; called by muse, mutect2, varscan2
- TNFSF13 | c.744G>A p.V248= | Silent (SNP) | VAF 131/481 reads (27%) | catalogued as COSV53432316, COSV53434044; called by muse, mutect2, varscan2
- TRANK1 | c.7887G>A p.L2629= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as rs1213495298, COSV57163551; called by muse, mutect2, varscan2
- TRBV20-1 | c.318C>T p.Y106= | Silent (SNP) | VAF 153/396 reads (39%) | called by muse, mutect2, varscan2
- TRIM3 | c.114G>A p.L38= | Silent (SNP) | VAF 97/294 reads (33%) | catalogued as COSV61985551; called by muse, mutect2, varscan2
